Somatic mutation profile of tumor specimen TCGA-EM-A3O3-01A (aliquot TCGA-EM-A3O3-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3O3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 83.5 years (30,500 days).
Specimen TCGA-EM-A3O3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8962676-0bd8-4011-8756-71cd127670d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3O3-10A (Blood Derived Normal), aliquot TCGA-EM-A3O3-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abedb5ff-1cb0-4a08-b1a9-c9260ea57234

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Frame Shift Del 4, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BDP1 | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV62428920; called by muse, mutect2, varscan2
- BTBD3 | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); catalogued as rs370789350; called by muse, mutect2, varscan2
- C7orf57 | c.482A>C p.E161A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62361712, COSV62363351; called by muse, mutect2, varscan2
- CASP6 | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54460200; called by muse, mutect2, varscan2
- CPS1 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242530; called by muse, mutect2, varscan2
- CPS1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345022979, COSV99242532; called by muse, mutect2, varscan2
- DDX42 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63789301; called by muse, mutect2, varscan2
- FLT3LG | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV52618222, COSV52618688; called by muse, mutect2, varscan2
- GULP1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63064945; called by muse, mutect2, varscan2
- ITGB8 | c.128A>C p.E43A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV56004918; called by muse, varscan2
- NFATC1 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs754370015, COSV53695123; called by muse, mutect2, varscan2
- OR10G4 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs772792672, COSV57976595; called by muse, mutect2, varscan2
- OR5D13 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV62332692; called by muse, mutect2, varscan2
- PCGF2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs765654378; called by muse, mutect2, varscan2
- PDCD4 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV54521808; called by muse, mutect2, varscan2
- SCAF1 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1209460329, COSV62182303; called by muse, mutect2, varscan2
- SMG7 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1002611762, COSV61629676; called by muse, mutect2, varscan2
- SOAT1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs1230944302, COSV62652648; called by muse, mutect2, varscan2
- STAB2 | c.7213C>A p.L2405M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV66334176; called by muse, mutect2, varscan2
- TRPV3 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.159); catalogued as COSV56788526, COSV56789739; called by muse, mutect2, varscan2
- ZMIZ1 | c.1975C>G p.P659A | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); catalogued as rs1398082973, COSV57889652; called by muse, mutect2, varscan2
- ZNF497 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as COSV54049724; called by muse, mutect2, varscan2
- ZNF613 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV53270831; called by muse, mutect2, varscan2
- EPRS1 | c.4061_4070del p.K1354Tfs*18 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel
- GOLGA4 | c.3088_3097del p.E1030Lfs*41 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- RPL22 | c.69_73del p.D24Hfs*15 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- UBN2 | c.2995del p.L999Wfs*16 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- BRAT1 | c.810C>T p.P270= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs775096485, COSV100500744, COSV61394078; called by muse, mutect2, varscan2
- HK3 | c.1927T>C p.L643= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as COSV52836910; called by muse, mutect2, varscan2
- MUC5B | c.11070C>A p.T3690= | Silent (SNP) | VAF 134/416 reads (32%) | catalogued as rs778594445, COSV71590014; called by muse, mutect2, varscan2
- NINL | c.57C>T p.C19= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as rs753697173, COSV53998606; called by muse, mutect2, varscan2
- OBSCN | c.6834A>G p.E2278= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as rs1476069770, COSV52739815; called by muse, mutect2, varscan2
- OTUD7B | c.246C>T p.I82= | Silent (SNP) | VAF 9/188 reads (5%) | catalogued as rs1553777522, COSV64915092; called by muse, mutect2
- PKHD1 | c.1674C>T p.L558= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as rs1562248370, COSV61860531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFLNB | c.315G>A p.K105= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs373345868; called by muse, mutect2, varscan2
- ZFYVE27 | c.99A>G p.P33= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1487529564, COSV61746294; called by muse, mutect2, varscan2
- NBPF25P | n.1795T>A | RNA (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
